RC case RC-B65K — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/851211d3-2077-40a2-b2c7-69d0d5c427e4

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1948; Vital status: Dead; Days to death: 1,449 days (4.0 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Grenada.

Diagnoses (6)
1. Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants) (the primary disease): ICD-O-3 morphology code: 9827/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 67.3 years (24,573 days); Year of diagnosis: 2015; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low Risk; Sites of involvement: Peripheral blood.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Interferon + Other; Initial disease status: Initial Diagnosis; Days to treatment start: 714 days (2.0 years); Days to treatment end: 790 days (2.2 years); Treatment outcome: Treatment Stopped Due to Toxicity; Reason treatment ended: Adverse Event; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Progressive Disease; Regimen or line of therapy: EPOCH; Days to treatment start: 1,233 days (3.4 years); Days to treatment end: 1,323 days (3.6 years); Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Anti-CD25-PBD Antibody-drug Conjugate ADCT-301; Initial disease status: Progressive Disease; Days to treatment start: 1,351 days (3.7 years); Days to treatment end: 1,371 days (3.8 years); Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Methotrexate; Initial disease status: Progressive Disease; Days to treatment start: 1,397 days (3.8 years); Days to treatment end: 1,414 days (3.9 years); Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate + Mogamulizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,417 days (3.9 years); Days to treatment end: 1,421 days (3.9 years); Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Progression (histology not recorded by GDC). Age at diagnosis: 69.2 years (25,272 days); Days to diagnosis: 699 days (1.9 years).
3. Progression (histology not recorded by GDC). Age at diagnosis: 70.6 years (25,787 days); Days to diagnosis: 1,214 days (3.3 years).
4. Progression (histology not recorded by GDC). Age at diagnosis: 71.0 years (25,921 days); Days to diagnosis: 1,348 days (3.7 years).
5. Progression (histology not recorded by GDC). Age at diagnosis: 71.1 years (25,964 days); Days to diagnosis: 1,391 days (3.8 years).
6. Progression (histology not recorded by GDC). Age at diagnosis: 71.2 years (26,005 days); Days to diagnosis: 1,432 days (3.9 years).

Follow-up (8 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100.
- Day 699 (progression): Progression or recurrence: Yes; Days to progression: 699 days (1.9 years).
- Day 1,214 (progression): Progression or recurrence: Yes; Days to progression: 1,214 days (3.3 years).
- Day 1,348 (progression): Progression or recurrence: Yes; Days to progression: 1,348 days (3.7 years).
- Day 1,391 (progression): Progression or recurrence: Yes; Days to progression: 1,391 days (3.8 years).
- Day 1,432 (progression): Progression or recurrence: Yes; Days to progression: 1,432 days (3.9 years).
- Day 1,449 (end of treatment course 1): Disease response: With Tumor.
- Follow-up contact recording only the day: day 714.

Molecular and laboratory tests
- Lactate Dehydrogenase 228 U/L [Blood test normal range upper: 246].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 102.5 kg; Height: 185 cm; BMI: 29.9.
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension / Diverticulitis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Uterine Cancer.

Biospecimens (2 samples)
- Sample RC-B65K-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B65K-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
